Somatic mutation profile of tumor specimen TCGA-A6-5661-01A (aliquot TCGA-A6-5661-01A-01D-1650-10) from TCGA case TCGA-A6-5661, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 80.6 years (29,446 days).
Specimen TCGA-A6-5661-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f0d4687-27cc-4a16-b7c6-dd5378b8f97a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5661-10A (Blood Derived Normal), aliquot TCGA-A6-5661-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb12b026-04d6-4882-b004-f78878fe25d7

The open-access MAF lists 1,461 somatic variants for this specimen: 1,100 protein-altering or splice-affecting, 331 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 774, Silent 331, Frame Shift Del 163, Frame Shift Ins 75, Nonsense Mutation 44, Splice Site 17, Intron 15, In Frame Del 14, Splice Region 9, RNA 6, 3'UTR 5, Translation Start Site 3.

Variants (750 of 1,461; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AR | c.2191G>A p.V731M | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs137852571, COSV65955393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CACNA1A | c.3544dup p.L1182Pfs*38 | Frame Shift Ins (INS) | VAF 18/90 reads (20%) | catalogued as rs757953057; ClinVar: pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.1147T>C p.W383R | Missense Mutation (SNP) | VAF 104/245 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62690170, COSV62701352, COSV62704397; called by muse, varscan2
- ESRRB | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | catalogued as rs202023138, COSV55062062; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 15/204 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2
- HTRA1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs587776445, CM112568, COSV64563845; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1201del p.R401Gfs*18 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs397508082, CX097215, COSV50099837; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KLHL3 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 44/170 reads (26%) | catalogued as rs199469638, CM120718, COSV100553458, COSV59054692; ClinVar: pathogenic; called by muse, mutect2, varscan2
- L1CAM | c.1267+1G>A p.X423_splice | Splice Site (SNP) | VAF 8/51 reads (16%) | catalogued as rs1557092247, CS982244, COSV62828214; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.27del p.Q10Rfs*15 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs587777613; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- NANS | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.738); catalogued as rs140402727, COSV52963994; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 55/179 reads (31%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PALB2 | c.839del p.N280Tfs*8 | Frame Shift Del (DEL) | VAF 38/204 reads (19%) | catalogued as rs1555461597; ClinVar: pathogenic; called by mutect2, varscan2
- RAG1 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs199474676, CM107798, COSV55023823; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- RB1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 57/256 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs772678500, COSV57305106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC37A4 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193302903, CM980800, COSV100421525; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918642, CM910358, CM910359, COSV63752484; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAG1 | c.3261del p.K1087Nfs*3 | Frame Shift Del (DEL) | VAF 144/546 reads (26%) | catalogued as rs1553789166; ClinVar: likely pathogenic; called by mutect2, pindel
- A2ML1 | c.2212C>A p.L738I | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100228796, COSV55291298; called by muse, mutect2, varscan2
- A4GALT | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.231); catalogued as COSV99966791; called by muse, varscan2
- ABCA9 | c.3865C>T p.R1289W | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs370277695; called by muse, mutect2, varscan2
- ABCD1 | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs1557055332, COSV54384900; called by muse, mutect2, varscan2
- ABL1 | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs750196179, COSV59330252; called by muse, varscan2
- ABR | c.370G>A p.A124T (on ENST00000302538 / NM_021962.5; = p.A87T on NM_001092.5) | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1274518801, COSV52141619; called by muse, mutect2, varscan2
- AC008397.2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV62747714; called by muse, mutect2, varscan2
- ACAP3 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs762533290, COSV61222269; called by muse, varscan2
- ACOX1 | c.1661T>A p.V554D | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53133409; called by muse, mutect2
- ACTN2 | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 55/171 reads (32%) | catalogued as COSV63975191; called by muse, mutect2, varscan2
- ACTN4 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766315573, COSV53146246; called by muse, mutect2, varscan2
- ACTR1A | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs764802984, COSV64023383; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 86/136 reads (63%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM29 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV63663909; called by muse, mutect2
- ADAMTS12 | c.4143T>G p.S1381R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV61263692; called by muse, mutect2, varscan2
- ADAMTS12 | c.3788C>T p.T1263M | Missense Mutation (SNP) | VAF 140/482 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs757177041, COSV100710420, COSV61263698; called by muse, mutect2, varscan2
- ADAMTS13 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782601193, COSV63021363; called by muse, mutect2, varscan2
- ADAMTS13 | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs138770906; called by muse, mutect2, varscan2
- ADAMTS4 | c.2057G>T p.S686I | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV63490251; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1651G>A p.G551S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs757026814, COSV54998678; called by muse, mutect2, varscan2
- ADCY2 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.012); catalogued as COSV100602568, COSV100604233; called by muse, varscan2
- ADGRB2 | c.3421C>A p.L1141M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV57072776, COSV57073898; called by muse, mutect2, varscan2
- ADGRF4 | c.112A>C p.S38R | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV51952688; called by muse, mutect2, varscan2
- ADGRG3 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as COSV59651239; called by muse, mutect2, varscan2
- ADM | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53403148; called by muse, mutect2, varscan2
- AFAP1 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61795753; called by muse, mutect2, varscan2
- AFF2 | c.1508G>T p.S503I | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53978328, COSV53990897; called by muse, mutect2, varscan2
- AGAP2 | c.3062C>A p.P1021H (on ENST00000547588 / NM_001122772.2; = p.P665H on NM_014770.4) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57728270; called by muse, varscan2
- AGAP3 | c.1940C>A p.P647H (on ENST00000622464; = p.P683H on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV68244854, COSV68246386; called by muse, mutect2, varscan2
- AGBL5 | c.2437del p.R813Gfs*68 | Frame Shift Del (DEL) | VAF 40/106 reads (38%) | catalogued as rs759542168; called by mutect2, varscan2
- AGK | c.1055A>C p.K352T | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV62594600; called by muse, mutect2
- AHNAK2 | c.10154C>T p.A3385V | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.042); catalogued as rs765830107, COSV60908334; called by muse, mutect2, varscan2
- AKAP13 | c.7802G>A p.R2601H (on ENST00000394518 / NM_007200.5; = p.R2605H on NM_006738.6) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs369963716; called by muse, mutect2, varscan2
- AKAP9 | c.2498A>G p.K833R | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs537099180, COSV62347230; called by muse, mutect2, varscan2
- AL035460.1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs763432652, COSV63028171; called by muse, mutect2, varscan2
- ALG13 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 136/429 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV52639398; called by muse, mutect2, varscan2
- ALKBH6 | c.247G>A p.V83M (on ENST00000252984 / NM_001297701.2; = p.V111M on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.86); catalogued as rs377096899; called by muse, mutect2, varscan2
- ALPK2 | c.3556C>T p.R1186C | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as rs139032503; called by muse, mutect2, varscan2
- ALPK2 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 104/336 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV64493383; called by muse, mutect2, varscan2
- AMFR | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs1258439560, COSV51921608; called by muse, mutect2, varscan2
- AMMECR1L | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV55760731; called by muse, mutect2, varscan2
- AMPD3 | c.2225G>A p.R742Q (on ENST00000396553 / NM_001025389.2; = p.R751Q on NM_000480.3) | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375048503, COSV67332667; called by muse, mutect2, varscan2
- AMY2A | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 200/1874 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1470843723, COSV70214528; called by muse, mutect2, varscan2
- ANK2 | c.2831C>T p.S944F | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52162842; called by muse, mutect2
- ANK2 | c.4842T>A p.Y1614* | Nonsense Mutation (SNP) | VAF 26/212 reads (12%) | catalogued as COSV52162870; called by muse, varscan2
- ANK2 | c.5191G>A p.G1731S | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as COSV52162877; called by muse, mutect2, varscan2
- ANKRD11 | c.2748C>A p.N916K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV56361784; called by muse, mutect2, varscan2
- ANKRD11 | c.678G>T p.E226D | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.991); catalogued as COSV56361790; called by muse, mutect2, varscan2
- ANKRD17 | c.6744del p.L2249Yfs*84 | Frame Shift Del (DEL) | VAF 68/233 reads (29%) | catalogued as COSV58214969; called by mutect2, pindel, varscan2
- ANKRD52 | c.2855G>A p.G952D | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV57288111; called by muse, mutect2, varscan2
- ANTXR2 | c.1130A>T p.D377V | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56315630; called by muse, mutect2
- AOAH | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150499149; called by muse, mutect2, varscan2
- AOC2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376064787; called by muse, mutect2, varscan2
- AP3D1 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs754925189, COSV61428661; called by muse, mutect2, varscan2
- ARHGAP31 | c.2649G>T p.Q883H | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.808); catalogued as COSV99957787; called by muse, mutect2, varscan2
- ARHGEF16 | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV65682130; called by muse, mutect2, varscan2
- ARHGEF6 | c.1249C>T p.Q417* | Nonsense Mutation (SNP) | VAF 89/281 reads (32%) | catalogued as COSV51691215; called by muse, mutect2, varscan2
- ARIH2 | c.980T>C p.L327P | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62704882; called by muse, mutect2, varscan2
- ARMCX1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV65705210; called by muse, mutect2, varscan2
- ASAP2 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55632150; called by muse, mutect2, varscan2
- ASIC5 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV101539809; called by muse, mutect2
- ASPG | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750346767, COSV71933803; called by muse, mutect2, varscan2
- ATAD3A | c.1634C>G p.A545G | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV59233583; called by muse, mutect2, varscan2
- ATP12A | c.76del p.D26Mfs*9 | Frame Shift Del (DEL) | VAF 54/250 reads (22%) | catalogued as COSV99517674; called by mutect2, pindel, varscan2
- ATP13A5 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60869715; called by muse, mutect2, varscan2
- ATP2B4 | c.261dup p.K88Qfs*40 | Frame Shift Ins (INS) | VAF 49/141 reads (35%) | catalogued as rs769726180; called by mutect2, varscan2
- ATP7B | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54438878; called by muse, mutect2, varscan2
- ATP8B3 | c.2327C>T p.A776V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1487616128, COSV59543098; called by muse, mutect2, varscan2
- ATRNL1 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs781892443, COSV58075293; called by muse, mutect2, varscan2
- AVPR1B | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV65638154; called by muse, mutect2, varscan2
- AXIN1 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as rs377025983; called by muse, mutect2, varscan2
- B4GALNT1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774565348, COSV57542946, COSV57542950; called by muse, mutect2, varscan2
- BAHCC1 | c.2550dup p.G851Rfs*223 | Frame Shift Ins (INS) | VAF 15/44 reads (34%) | catalogued as rs1555653824; called by mutect2, pindel, varscan2
- BAIAP3 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752184065, COSV60980374; called by muse, mutect2, varscan2
- BCL2L2 | c.529G>C p.A177P | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51636005; called by muse, mutect2, varscan2
- BCOR | c.2514dup p.K839Qfs*5 | Frame Shift Ins (INS) | VAF 29/124 reads (23%) | catalogued as rs1394942244; called by mutect2, pindel, varscan2
- BEND7 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs745972440, COSV61989162; called by muse, mutect2, varscan2
- BHLHE22 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100417975; called by muse, mutect2, varscan2
- BLK | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751422253, COSV52050663, COSV52052419; called by muse, mutect2, varscan2
- BMPR2 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65809663; called by muse, mutect2, varscan2
- BPHL | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 54/306 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100984582; called by muse, varscan2
- BPI | c.17C>T p.A6V (on ENST00000262865; = p.A2V on NM_001725.3) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV53405896; called by muse, varscan2
- BPI | c.94G>A p.V32I (on ENST00000262865; = p.V28I on NM_001725.3) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs776005510, COSV53403846; called by muse, varscan2
- BPIFB6 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs768708685, COSV62755341; called by muse, mutect2, varscan2
- BRSK2 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as rs746469963, COSV57543540; called by muse, mutect2, varscan2
- BTBD11 | c.2696C>A p.P899H (on ENST00000280758 / NM_001018072.2; = p.P436H on NM_001017523.2) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55024997, COSV55038261; called by muse, mutect2, varscan2
- BTBD3 | c.1248C>A p.S416R | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV54779391; called by muse, mutect2, varscan2
- C12orf40 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV61132824; called by muse, mutect2, varscan2
- C1R | c.943C>T p.R315C (on ENST00000536053 / NM_001354346.2; = p.R301C on NM_001733.7) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs749119957, COSV101599213; called by muse, varscan2
- C20orf194 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs368275201; called by muse, mutect2, varscan2
- C22orf15 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs779027015, COSV59418066; called by muse, mutect2, varscan2
- C2orf50 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV101059477; called by muse, mutect2
- C4orf3 | c.194dup p.L65Ffs*20 | Frame Shift Ins (INS) | VAF 28/100 reads (28%) | catalogued as rs760121305; called by mutect2, pindel, varscan2
- C5orf22 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 210/609 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV57598537; called by muse, mutect2, varscan2
- CA12 | c.358C>A p.L120M | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.775); catalogued as COSV51605948; called by muse, mutect2, varscan2
- CAB39L | c.285del p.D96Mfs*2 | Frame Shift Del (DEL) | VAF 38/235 reads (16%) | catalogued as COSV61714509; called by mutect2, pindel, varscan2
- CABP2 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs918884851, COSV53708900; called by muse, mutect2, varscan2
- CACNA1F | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs1360293270, COSV59904646; called by muse, mutect2, varscan2
- CACNA1I | c.276C>G p.N92K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60809363; called by muse, mutect2, varscan2
- CACYBP | c.379A>G p.M127V | Missense Mutation (SNP) | VAF 106/318 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1255048526, COSV62881229; called by muse, mutect2, varscan2
- CAMTA1 | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as rs150582508; called by mutect2, varscan2
- CAMTA2 | c.3415C>T p.R1139C | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99236842; called by muse, mutect2, varscan2
- CAPN5 | c.1358C>T p.T453M (on ENST00000456580; = p.T413M on NM_004055.5) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.227); catalogued as rs370528920; called by muse, mutect2, varscan2
- CAPRIN2 | c.2043+2T>A p.X681_splice | Splice Site (SNP) | VAF 21/69 reads (30%) | catalogued as COSV51832789; called by muse, mutect2, varscan2
- CARTPT | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV57115036; called by muse, mutect2, varscan2
- CASQ2 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54770781; called by muse, mutect2, varscan2
- CAVIN2 | c.329C>G p.T110R | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58424350, COSV58425725; called by muse, mutect2, varscan2
- CBX3 | c.42del p.K14Nfs*23 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | catalogued as COSV61761904; called by mutect2, pindel, varscan2
- CCDC146 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 41/131 reads (31%) | catalogued as rs371350411; called by muse, mutect2, varscan2
- CCDC174 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV99514596; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 109/450 reads (24%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC181 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 126/412 reads (31%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.661); catalogued as rs1299782124, COSV100890401; called by muse, mutect2, varscan2
- CCDC63 | c.1471C>A p.L491I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57528703; called by muse, mutect2, varscan2
- CCN5 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as rs573175219, COSV99509492; called by muse, varscan2
- CCNA1 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs748235047, COSV55221766; called by muse, mutect2, varscan2
- CCNB3 | c.3668C>A p.P1223H | Missense Mutation (SNP) | VAF 85/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52074150; called by muse, mutect2, varscan2
- CCT5 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 71/295 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as rs768768696, COSV54724123; called by muse, mutect2, varscan2
- CD276 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562558740, COSV59203915; called by muse, mutect2, varscan2
- CDADC1 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as rs141868508; called by muse, mutect2, varscan2
- CDAN1 | c.1250T>G p.V417G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV99142518; called by muse, mutect2, varscan2
- CDH1 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs780399325, COSV55733357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH11 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 45/195 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV51762973; called by muse, mutect2, varscan2
- CDHR3 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 120/407 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs765982493, COSV58417555; called by muse, mutect2, varscan2
- CDR2 | c.1100G>A p.C367Y | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV51676355; called by muse, mutect2, varscan2
- CDRT1 | c.574T>C p.S192P | Missense Mutation (SNP) | VAF 91/271 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV55411856; called by muse, mutect2, varscan2
- CELF6 | c.1397G>T p.R466M | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54716644; called by muse, mutect2, varscan2
- CELSR3 | c.7592G>A p.R2531K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV50864733; called by muse, mutect2, varscan2
- CELSR3 | c.5896C>T p.Q1966* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as COSV50864897; called by muse, mutect2, varscan2
- CEMIP | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs981579979, COSV54993157, COSV99587095; called by muse, mutect2, varscan2
- CEP170B | c.2782C>T p.R928* (on ENST00000453495; = p.R857* on NM_015005.3) | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs924324366, COSV69025182; called by muse, mutect2, varscan2
- CEP250 | c.3778-1G>T p.X1260_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as COSV61170432; called by muse, mutect2, varscan2
- CFAP74 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as rs367581557, COSV54568207; called by muse, mutect2, varscan2
- CHAC1 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.284); catalogued as COSV71436100; called by muse, mutect2, varscan2
- CHMP1B | c.72dup p.C25Mfs*3 | Frame Shift Ins (INS) | VAF 29/73 reads (40%) | catalogued as rs756274240; called by mutect2, pindel, varscan2
- CHRNA2 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs761054762, COSV53557798; ClinVar: uncertain significance; called by mutect2, varscan2
- CHRNA5 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775819304, COSV55138489; called by muse, mutect2, varscan2
- CHST11 | c.83T>G p.L28R | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100359963; called by muse, mutect2
- CKAP2 | c.1189G>A p.G397R (on ENST00000378037 / NM_001098525.2; = p.G396R on NM_018204.5) | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as COSV51622381; called by muse, mutect2
- CKAP5 | c.4133G>A p.R1378H | Missense Mutation (SNP) | VAF 88/257 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56368116; called by muse, mutect2, varscan2
- CLASP1 | c.3961C>T p.R1321W | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372875621, COSV55325016; called by muse, mutect2, varscan2
- CLGN | c.1522del p.T508Pfs*12 | Frame Shift Del (DEL) | VAF 302/1087 reads (28%) | catalogued as rs1217577246; called by mutect2, pindel, varscan2
- CLTC | c.1403A>G p.K468R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as COSV52248016; called by mutect2, varscan2
- CLUH | c.1595G>A p.R532Q (on ENST00000435359; = p.R570Q on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as rs775496210, COSV70928766; called by muse, mutect2, varscan2
- CNGA1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs767503938, COSV62054413; called by muse, mutect2, varscan2
- CNKSR1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs374260381; called by mutect2, varscan2
- CNOT1 | c.5479G>T p.G1827C | Missense Mutation (SNP) | VAF 46/329 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV55317203; called by muse, mutect2, varscan2
- CNTLN | c.1082A>G p.D361G | Missense Mutation (SNP) | VAF 110/304 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52079943; called by muse, mutect2, varscan2
- CNTNAP3 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs1385962260, COSV99905262; called by muse, mutect2, varscan2
- CNTNAP5 | c.613A>C p.I205L | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV70487527; called by muse, mutect2, varscan2
- COBLL1 | c.3541T>C p.S1181P (on ENST00000392717; = p.S1143P on NM_014900.5) | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99528733; called by muse, mutect2
- COG6 | c.406del p.T136Pfs*11 | Frame Shift Del (DEL) | VAF 110/770 reads (14%) | catalogued as COSV62995223; called by mutect2, pindel, varscan2
- COL12A1 | c.5599G>A p.A1867T | Missense Mutation (SNP) | VAF 86/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59396665; called by muse, mutect2, varscan2
- COL12A1 | c.2512C>A p.P838T | Missense Mutation (SNP) | VAF 124/358 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV100486610; called by muse, mutect2, varscan2
- COL22A1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as rs1295033199, COSV100276279; called by muse, varscan2
- COL28A1 | c.1864G>A p.V622I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV68082216; called by muse, mutect2, varscan2
- COL5A3 | c.4421G>A p.R1474H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs370182126; called by muse, mutect2, varscan2
- COL6A1 | c.958-1G>T p.X320_splice | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as CS1312452, COSV62613396; called by muse, mutect2, varscan2
- COL6A6 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767928089, COSV62026096; called by muse, mutect2, varscan2
- COL8A2 | c.864G>T p.L288F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.552); catalogued as COSV57441926; called by muse, mutect2, varscan2
- COLEC12 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs1001323032, COSV68370812; called by muse, mutect2, varscan2
- COMMD10 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.356); catalogued as COSV57236903; called by muse, mutect2, varscan2
- CPLANE1 | c.7670C>T p.A2557V | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57061008; called by muse, mutect2, varscan2
- CRACR2B | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs974468949, COSV58989984; called by muse, mutect2, varscan2
- CRBN | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs151127854; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs776815858, COSV65677193; called by muse, varscan2
- CSMD1 | c.5452G>A p.G1818S (on ENST00000520002; = p.G1817S on NM_033225.6) | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769067339, COSV59281721; called by muse, mutect2, varscan2
- CSMD1 | c.5299G>A p.E1767K (on ENST00000520002; = p.E1766K on NM_033225.6) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1305727463, COSV59345424; called by muse, varscan2
- CSMD1 | c.3653G>A p.C1218Y (on ENST00000520002; = p.C1217Y on NM_033225.6) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs1223737405, COSV59296156, COSV59359660; called by muse, mutect2, varscan2
- CSMD2 | c.3587G>A p.S1196N | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.058); catalogued as COSV99595783; called by muse, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 30/110 reads (27%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CSNK1D | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53924049; called by muse, varscan2
- CSTF3 | c.613dup p.M205Nfs*3 | Frame Shift Ins (INS) | VAF 132/426 reads (31%) | catalogued as rs1300471016; called by mutect2, varscan2
- CTDSP2 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs772434435, COSV66079929; called by muse, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CTNND1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.703); catalogued as COSV62383707; called by muse, mutect2
- CTRL | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs144794688; called by muse, mutect2, varscan2
- CTSA | c.342del p.Y115Ifs*5 | Frame Shift Del (DEL) | VAF 126/416 reads (30%) | catalogued as rs755100318; called by mutect2, pindel, varscan2
- CTTNBP2 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 84/269 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.395); catalogued as COSV50389744; called by muse, mutect2, varscan2
- CTU2 | c.1073C>A p.P358H | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56337879; called by muse, mutect2, varscan2
- CUL9 | c.1331A>C p.E444A | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV52728989; called by muse, mutect2
- CYBRD1 | c.21G>T p.W7C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58426680; called by muse, mutect2, varscan2
- CYP19A1 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); catalogued as rs1474563724, COSV53059563; called by muse, mutect2, varscan2
- CYP4F2 | c.986-3del | Splice Region (DEL) | VAF 9/66 reads (14%) | catalogued as rs1271723179; called by mutect2, pindel, varscan2
- CYP4F3 | c.1275del p.F425Lfs*54 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs1437242665; called by mutect2, pindel, varscan2
- CYP4F8 | c.976A>G p.M326V | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100358260; called by muse, mutect2
- CYP7A1 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs1210055982, COSV56963769, COSV56964129; called by muse, mutect2
- CYP7A1 | c.206G>A p.C69Y | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56963781; called by muse, mutect2, varscan2
- DAG1 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.731); catalogued as rs1254715826, COSV58184556; called by muse, mutect2, varscan2
- DAXX | c.1884dup p.C629Lfs*29 | Frame Shift Ins (INS) | VAF 34/113 reads (30%) | catalogued as rs1268651006; called by mutect2, varscan2
- DCAF15 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.725); catalogued as rs1425086945, COSV54330190; called by muse, mutect2, varscan2
- DCC | c.1863G>T p.V621= | Splice Region (SNP) | VAF 20/89 reads (22%) | catalogued as COSV59104374; called by muse, mutect2, varscan2
- DEFB119 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs746865254, COSV53620422, COSV53620448; called by muse, mutect2, varscan2
- DGKD | c.3197C>T p.P1066L (on ENST00000264057 / NM_152879.3; = p.P1022L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs373084771; called by muse, mutect2, varscan2
- DGKZ | c.1265G>T p.G422V (on ENST00000454345 / NM_001105540.2; = p.G234V on NM_003646.4) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58988690; called by muse, mutect2, varscan2
- DGKZ | c.3041C>T p.T1014M (on ENST00000454345 / NM_001105540.2; = p.T826M on NM_003646.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1165234444, COSV58984478; called by muse, mutect2, varscan2
- DHX34 | c.3344T>C p.L1115P | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs762513967, COSV60895558; called by muse, mutect2
- DIDO1 | c.3541+6C>T | Splice Region (SNP) | VAF 12/49 reads (24%) | catalogued as rs765548395, COSV56621287; called by muse, mutect2, varscan2
- DIP2B | c.4600G>A p.V1534I | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs569460179, COSV56584488; called by muse, mutect2, varscan2
- DIP2C | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs372112681, COSV55159474; called by muse, mutect2, varscan2
- DISP1 | c.583A>G p.M195V | Missense Mutation (SNP) | VAF 181/549 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs780687540, COSV52659481, COSV52663815; called by muse, mutect2, varscan2
- DIXDC1 | c.1826G>A p.R609Q (on ENST00000440460 / NM_001037954.4; = p.R398Q on NM_033425.4) | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1555177782, COSV59463874; called by muse, varscan2
- DKK3 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58868830; called by muse, mutect2, varscan2
- DLAT | c.1105G>T p.G369W | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54770878; called by muse, mutect2, varscan2
- DLC1 | c.2393G>A p.R798H (on ENST00000276297 / NM_001348081.2; = p.R361H on NM_006094.5) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs755906883, COSV52305962; called by muse, mutect2, varscan2
- DLGAP1 | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV59806069; called by muse, mutect2, varscan2
- DMPK | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1405814711, COSV52178697; called by muse, mutect2, varscan2
- DMRT3 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99506097; called by muse, mutect2, varscan2
- DMXL1 | c.4982del p.N1661Tfs*4 | Frame Shift Del (DEL) | VAF 98/312 reads (31%) | catalogued as rs1029723468; called by mutect2, pindel, varscan2
- DNA2 | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs529850423, COSV100622632, COSV64428646; called by muse, varscan2
- DNAH2 | c.4768G>A p.D1590N | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs781350890, COSV66720014, COSV66721103; called by muse, mutect2, varscan2
- DNAH3 | c.6940C>T p.R2314C | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048642840, COSV54517579; called by muse, mutect2, varscan2
- DNAH5 | c.9914A>G p.D3305G | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV54227502; called by muse, mutect2, varscan2
- DNAH9 | c.6471G>T p.K2157N | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV52351652; called by muse, mutect2, varscan2
- DNAI2 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs192790912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC13 | c.2729G>A p.R910Q | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754878524, COSV99608195; called by muse, mutect2, varscan2
- DNAJC15 | c.312-1G>A p.X104_splice | Splice Site (SNP) | VAF 93/403 reads (23%) | catalogued as COSV64872294; called by muse, mutect2, varscan2
- DNM2 | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.506); catalogued as COSV58961458, COSV58962551; called by muse, mutect2, varscan2
- DOCK1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs372560858; called by muse, mutect2, varscan2
- DOCK11 | c.3550C>T p.R1184* | Nonsense Mutation (SNP) | VAF 556/1613 reads (34%) | catalogued as rs1050611235, COSV52239482, COSV99354591; called by muse, mutect2, varscan2
- DOCK4 | c.5789C>T p.A1930V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as rs776452844, COSV70236558; called by muse, mutect2, varscan2
- DPF1 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.219); catalogued as rs757077176, COSV62792865; called by muse, mutect2, varscan2
- DPF2 | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV52889493; called by muse, mutect2, varscan2
- DPH7 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs747961442, COSV53022314; called by muse, mutect2, varscan2
- DPP10 | c.367-1G>A p.X123_splice | Splice Site (SNP) | VAF 40/105 reads (38%) | catalogued as COSV59688863; called by muse, mutect2, varscan2
- DSPP | c.3175G>A p.D1059N | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV99218033; called by muse, varscan2
- DST | c.21149C>T p.A7050V (on ENST00000361203 / NM_001374722.1; = p.A4747V on NM_015548.5) | Missense Mutation (SNP) | VAF 132/381 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753316934, COSV55016524; called by muse, mutect2, varscan2
- DTX4 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs577423377, COSV57091027; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs762133243; called by mutect2, varscan2
- DUOX1 | c.453G>T p.W151C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100368536; called by muse, mutect2, varscan2
- DUOX2 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs1300558168, COSV50993077; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 60/247 reads (24%) | catalogued as rs746928635; called by mutect2, pindel, varscan2
- DYNC1H1 | c.12637C>T p.R4213W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64137320; called by muse, mutect2, varscan2
- DYNC2H1 | c.5477C>T p.A1826V | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62094933; called by muse, mutect2, varscan2
- DYNC2H1 | c.5668C>T p.Q1890* | Nonsense Mutation (SNP) | VAF 60/156 reads (38%) | catalogued as COSV62094935; called by muse, mutect2, varscan2
- DYNC2I1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs778102381, COSV101237861; called by muse, varscan2
- DYSF | c.2920G>A p.D974N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs200422222, COSV99249487; called by muse, mutect2, varscan2
- EDEM1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV99849425; called by muse, mutect2
- EFCAB13 | c.2110A>G p.K704E | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.142); catalogued as COSV58948961; called by muse, mutect2, varscan2
- EGR2 | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV99654314; called by muse, mutect2, varscan2
- EIF2AK4 | c.3008del p.P1003Hfs*17 | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | catalogued as rs1223356087; called by mutect2, pindel, varscan2
- EIF4ENIF1 | c.2417G>A p.R806H | Missense Mutation (SNP) | VAF 181/546 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs780468231, COSV57516162; called by muse, mutect2, varscan2
- ELMO1 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs751395548, COSV60305620; called by muse, mutect2, varscan2
- ELOVL1 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs1177680519, COSV60522182; called by muse, mutect2, varscan2
- EMC10 | c.581del p.P194Qfs*45 (on ENST00000334976 / NM_206538.4; = p.P194Qfs*74 on NM_175063.6) | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | catalogued as COSV100618505; called by mutect2, varscan2
- EMILIN1 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs199664509; called by muse, varscan2
- ENPP4 | c.1338T>A p.D446E | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV58089068; called by muse, mutect2, varscan2
- EP300 | c.4433G>A p.R1478H | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs756061989, COSV54334553; called by muse, mutect2, varscan2
- EP400 | c.8966C>A p.P2989H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV100202381; called by muse, varscan2
- EPB42 | c.197G>A p.G66E (on ENST00000441366 / NM_001114134.2; = p.G96E on NM_000119.3) | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55749912; called by muse, mutect2, varscan2
- EPC2 | c.1592G>T p.R531M | Missense Mutation (SNP) | VAF 139/439 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51544294; called by muse, mutect2, varscan2
- EPHA2 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV64453236; called by muse, mutect2, varscan2
- EPHA6 | c.70G>C p.A24P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.335); catalogued as COSV101065742; called by muse, mutect2, varscan2
- EPHA8 | c.2024A>G p.E675G | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51270353; called by muse, mutect2, varscan2
- EPHX4 | c.515dup p.M173Hfs*12 | Frame Shift Ins (INS) | VAF 32/290 reads (11%) | catalogued as rs765115164; called by mutect2, varscan2
- EPPIN | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV51489794; called by muse, mutect2, varscan2
- ERAP2 | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV65939797; called by muse, mutect2, varscan2
- ERCC6L | c.3302A>T p.N1101I | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as COSV57820777; called by muse, mutect2, varscan2
- ERI3 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.094); catalogued as rs779614935, COSV64831724; called by muse, mutect2, varscan2
- ERO1B | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772121664, COSV51595496; called by muse, mutect2, varscan2
- ETV1 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 180/542 reads (33%) | catalogued as COSV54143280; called by muse, mutect2, varscan2
- EVI2B | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 174/534 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV58364039; called by muse, mutect2, varscan2
- EXD3 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.058); catalogued as rs201793473; called by muse, mutect2, varscan2
- EXOC3 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV59266847; called by muse, mutect2, varscan2
- FADS2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99608518; called by muse, mutect2
- FAM135B | c.2083G>A p.V695I | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs374779918, COSV99426694; called by muse, mutect2, varscan2
- FAM162B | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs1321535137, COSV63920360; called by muse, mutect2, varscan2
- FAM178B | c.1889G>A p.R630H (on ENST00000490605 / NM_001122646.3; = p.R70H on NM_016490.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs1315063219, COSV59970184; called by muse, mutect2, varscan2
- FAM47C | c.599del p.P200Rfs*625 | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | catalogued as COSV63726734; called by mutect2, pindel, varscan2
- FAM83E | c.1258del p.E420Kfs*121 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs778486601; called by mutect2, pindel, varscan2
- FAT1 | c.11771G>A p.R3924H | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); catalogued as rs375087606, COSV71674323, COSV71676556; called by muse, mutect2, varscan2
- FAT4 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.199); catalogued as rs756378994, COSV101272882; called by muse, mutect2, varscan2
- FBN3 | c.4802G>A p.R1601H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as rs771565430, COSV54461878; called by muse, mutect2, varscan2
- FBP1 | c.881del p.G294Efs*11 | Frame Shift Del (DEL) | VAF 15/151 reads (10%) | catalogued as CM010885, CM106917; called by mutect2, pindel, varscan2
- FBXO21 | c.432dup p.E145* | Frame Shift Ins (INS) | VAF 26/90 reads (29%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXO25 | c.1087G>A p.D363N (on ENST00000382824 / NM_183421.2; = p.D287N on NM_012173.3) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.999); catalogued as rs999608722, COSV52337061; called by muse, mutect2, varscan2
- FBXW10 | c.2426C>A p.P809H | Missense Mutation (SNP) | VAF 138/462 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100111791; called by muse, varscan2
- FETUB | c.30C>A p.C10* | Nonsense Mutation (SNP) | VAF 33/109 reads (30%) | catalogued as COSV54005835; called by muse, mutect2, varscan2
- FGFR1OP2 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 103/332 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761470386, COSV57587187; called by muse, mutect2, varscan2
- FLG | c.3899A>G p.E1300G | Missense Mutation (SNP) | VAF 184/617 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1228777318, COSV64242368; called by muse, varscan2
- FLI1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs754322278, COSV61378190; called by muse, mutect2, varscan2
- FMN2 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60431661; called by muse, mutect2, varscan2
- FNDC1 | c.2600C>A p.S867Y | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV99794652, COSV99796994; called by muse, mutect2, varscan2
- FNDC4 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as rs1376445653, COSV53021399; called by muse, mutect2, varscan2
- FOXJ3 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1300696727, COSV62362513; called by muse, mutect2, varscan2
- FOXK1 | c.1507G>A p.V503I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.461); catalogued as rs1460949442, COSV100195898; called by muse, mutect2
- FOXP3 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs140222626, COSV66051439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRAS1 | c.10367del p.G3456Afs*3 | Frame Shift Del (DEL) | VAF 60/245 reads (24%) | catalogued as rs1350939361; called by mutect2, pindel, varscan2
- FRAT1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100925188; called by muse, mutect2, varscan2
- FREM1 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV66524225; called by muse, mutect2, varscan2
- FRY | c.6377C>A p.P2126Q | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV66570683; called by muse, mutect2, varscan2
- FSCB | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs371199022; called by muse, mutect2, varscan2
- FTO | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.033); catalogued as rs577569584, COSV67111857, COSV67113039, COSV67113404; called by muse, mutect2, varscan2
- FUZ | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs200831588, COSV58241751; called by muse, mutect2, varscan2
- FZR1 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1317988128, COSV100553896; called by muse, mutect2, varscan2
- G3BP2 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs767685659, COSV62976445; called by muse, mutect2, varscan2
- GALK1 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV52328183, COSV99564849; called by muse, mutect2, varscan2
- GALNT9 | c.1139G>A p.R380H (on ENST00000328957 / NM_001122636.2; = p.R14H on NM_021808.3) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375048132; called by muse, mutect2, varscan2
- GAN | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101634039; called by muse, mutect2
- GAREM1 | c.2181del p.R728Gfs*5 (on ENST00000269209 / NM_001242409.2; = p.R727Gfs*5 on NM_022751.3) | Frame Shift Del (DEL) | VAF 25/205 reads (12%) | catalogued as rs1372790960; called by mutect2, pindel, varscan2
- GAS2L3 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs764520871, COSV57157423; called by muse, mutect2, varscan2
- GCAT | c.770C>A p.T257N | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV99959953; called by muse, varscan2
- GCAT | c.818del p.X273_splice | Splice Site (DEL) | VAF 19/79 reads (24%) | catalogued as rs1569083487; called by mutect2, pindel, varscan2
- GJA3 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV53835264; called by muse, mutect2, varscan2
- GK | c.1654G>T p.A552S (on ENST00000427190 / NM_001205019.2; = p.A546S on NM_001128127.2) | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV66736925; called by muse, mutect2
- GLI3 | c.2873C>T p.A958V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373918769; called by muse, varscan2
- GLRA3 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761733852, COSV56862378; called by muse, varscan2
- GNAO1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV52614358, COSV52621333; called by muse, mutect2, varscan2
- GNL3L | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs756760969, COSV100328610; called by muse, varscan2
- GOLGA2 | c.805_807del p.K269del | In Frame Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs1158333485; called by pindel, varscan2
- GP9 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); catalogued as COSV56624161; called by muse, mutect2, varscan2
- GPAM | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs760239867, COSV62081256; called by muse, mutect2, varscan2
- GPR150 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV66168321; called by muse, mutect2, varscan2
- GPR158 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV66268265; called by muse, mutect2, varscan2
- GPR26 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 128/332 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52933349; called by muse, mutect2, varscan2
- GRHL3 | c.1562G>T p.R521M (on ENST00000350501 / NM_198174.3; = p.R526M on NM_021180.3) | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99359729; called by muse, varscan2
- GRIA2 | c.1231C>T p.L411F | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.155); catalogued as COSV52391624, COSV99646328; called by muse, varscan2
- GRID2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs377345301; called by muse, mutect2, varscan2
- GRIN1 | c.778C>A p.R260S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV100160763; called by muse, mutect2, varscan2
- GRIN2C | c.157del p.Q53Rfs*139 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs1286413245; called by mutect2, pindel
- GRIPAP1 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 33/345 reads (10%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.992); catalogued as COSV64552161; called by muse, mutect2
- GRM2 | c.1967G>A p.R656H | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767625940, COSV56585135; called by muse, mutect2, varscan2
- GRM4 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65213765; called by muse, mutect2, varscan2
- GRM7 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1288526507, COSV63144604; called by muse, mutect2, varscan2
- GSC2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555917851, COSV99324122; called by muse, mutect2, varscan2
- GTF3A | c.974T>G p.L325R | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs899741786, COSV63528588; called by muse, mutect2
- GTF3C3 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.86); catalogued as rs768859221, COSV55832246; called by muse, mutect2, varscan2
- GTPBP3 | c.1163C>A p.P388H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV61413621, COSV61414981; called by muse, mutect2, varscan2
- GUCY1A1 | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.166); catalogued as COSV56651937; called by muse, mutect2, varscan2
- HBS1L | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as rs1403297348, COSV59020974; called by muse, varscan2
- HCFC2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV57558724; called by muse, mutect2, varscan2
- HDAC9 | c.952C>A p.L318M | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.068); catalogued as COSV67773865; called by muse, mutect2, varscan2
- HEATR4 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100620185, COSV58573004; called by muse, mutect2, varscan2
- HECTD4 | c.9545C>T p.T3182M | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as rs577238057, COSV66392526; called by muse, varscan2
- HECW1 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as rs1413143821, COSV67828516; called by muse, mutect2, varscan2
- HEPH | c.3255dup p.R1086Qfs*4 (on ENST00000343002; = p.R819Qfs*4 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 124/559 reads (22%) | catalogued as rs750060613; called by pindel, varscan2
- HERC2 | c.778T>C p.F260L | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55325022; called by muse, mutect2, varscan2
- HES5 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.052); catalogued as COSV65830278; called by muse, mutect2, varscan2
- HEYL | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1210886751, COSV65721642; called by muse, mutect2, varscan2
- HFM1 | c.3383C>A p.P1128H | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV99646899; called by muse, mutect2, varscan2
- HIVEP3 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV56014367, COSV99914084; called by muse, mutect2, varscan2
- HK3 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.893); catalogued as rs774008286, COSV52840420; called by muse, mutect2, varscan2
- HMCN1 | c.13261G>T p.A4421S | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54902836, COSV54926829; called by muse, mutect2, varscan2
- HOGA1 | c.713del p.G238Afs*42 | Frame Shift Del (DEL) | VAF 27/111 reads (24%) | catalogued as rs760930050; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- HOXA1 | c.87_88insA p.S30Ifs*4 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as COSV56066386; called by pindel, varscan2
- HPS6 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762947367, COSV54624792; called by muse, mutect2, varscan2
- HS2ST1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 69/336 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as rs1023959139, COSV63350499; called by muse, mutect2, varscan2
- HS6ST3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.7); PolyPhen benign (0.251); catalogued as rs1268310394, COSV65009296; called by muse, mutect2, varscan2
- HSF1 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs782078876, COSV60048111; called by muse, mutect2, varscan2
- HUNK | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.656); catalogued as rs1352790395; called by muse, varscan2
- IBTK | c.3613C>T p.R1205W | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs375017614; called by muse, mutect2, varscan2
- IFI16 | c.618A>G p.I206M | Missense Mutation (SNP) | VAF 95/247 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.568); catalogued as rs937386240, COSV55534465; called by muse, mutect2, varscan2
- IFT122 | c.2805G>T p.K935N (on ENST00000348417 / NM_052989.3; = p.K876N on NM_018262.4) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as COSV56203410; called by muse, mutect2, varscan2
- IGHMBP2 | c.2226G>A p.M742I | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99662606; called by muse, varscan2
- IL17REL | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.36); catalogued as rs770559193, COSV58008093; called by mutect2, varscan2
- IL21R | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.552); catalogued as rs1423201047, COSV61970604; called by muse, mutect2, varscan2
- IL27 | c.31+1G>A p.X11_splice | Splice Site (SNP) | VAF 12/67 reads (18%) | catalogued as COSV63559654; called by muse, mutect2, varscan2
- IL6 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as COSV51732808; called by muse, mutect2, varscan2
- INHBE | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56988065; called by muse, varscan2
- INPP4A | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); catalogued as COSV50794492; called by muse, mutect2, varscan2
- IPO9 | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV64233812; called by muse, mutect2, varscan2
- IQGAP3 | c.2405G>A p.R802Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs560536788, COSV100752408; called by mutect2, varscan2
- IRS4 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100929747; called by muse, mutect2, varscan2
- ISLR2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV62303387; called by muse, mutect2, varscan2
- ITGA2B | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99289300; called by muse, mutect2, varscan2
- ITGBL1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1048167195, COSV66005980; called by muse, mutect2
- ITIH3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs779224896, COSV69649011; called by muse, mutect2, varscan2
- ITLN1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs147176765; called by muse, mutect2
- ITPR3 | c.1347C>A p.S449R | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV100968166; called by muse, mutect2, varscan2
- JADE1 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1377908620, COSV56904356; called by muse, mutect2, varscan2
- KALRN | c.7882G>A p.V2628I (on ENST00000360013 / NM_001024660.4; = p.V931I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.983); catalogued as rs762351590, COSV52256968; called by muse, mutect2, varscan2
- KANK2 | c.1940C>T p.T647M (on ENST00000586659 / NM_001379562.1; = p.T655M on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs765508139, COSV62008182; called by muse, mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 33/178 reads (19%) | catalogued as rs774820321; called by mutect2, varscan2
- KCNB1 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65571243; called by muse, mutect2, varscan2
- KCNG1 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781584436, COSV65369628; called by muse, varscan2
- KCNG2 | c.1235A>G p.Y412C | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60267988; called by muse, mutect2, varscan2
- KCNH1 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1049229741, COSV99661694; called by muse, mutect2, varscan2
- KCNK1 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64035192; called by muse, mutect2, varscan2
- KCNK13 | c.1171del p.V391Wfs*7 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as rs766469179, COSV56415804; called by mutect2, varscan2
- KDM1B | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99924708; called by muse, mutect2, varscan2
- KDM3B | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58690978; called by muse, mutect2, varscan2
- KDM5B | c.4267C>T p.R1423W | Missense Mutation (SNP) | VAF 174/534 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs751400477, COSV52507308, COSV52508150; called by muse, mutect2, varscan2
- KHDRBS3 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.358); catalogued as rs376433950; called by muse, mutect2, varscan2
- KIAA1109 | c.10763T>C p.V3588A | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52664511; called by muse, mutect2
- KIF12 | c.1403G>A p.R468H (on ENST00000640217; = p.R330H on NM_138424.1) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs372317733; called by muse, mutect2, varscan2
- KIF13B | c.3070C>T p.R1024W | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781387599, COSV72954312; called by muse, mutect2, varscan2
- KIF17 | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as rs772247964, COSV56118484; called by muse, mutect2, varscan2
- KIF21B | c.307A>G p.M103V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59758562; called by muse, mutect2
- KIF26B | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV69462955; called by muse, mutect2
- KIF26B | c.2342C>T p.A781V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs145521032, COSV63642172; called by muse, mutect2, varscan2
- KIRREL2 | c.1953del p.C652Afs*79 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs761116739, COSV52880030; called by mutect2, pindel, varscan2
- KIRREL3 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs200090559; called by muse, mutect2, varscan2
- KLC1 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs926694130, COSV55808068; called by muse, mutect2, varscan2
- KLHL15 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV100044450; called by muse, varscan2
- KLHL40 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV55134719; called by muse, mutect2, varscan2
- KLKB1 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs145932193, COSV99250470; called by muse, varscan2
- KLRK1 | c.102G>A p.W34* | Nonsense Mutation (SNP) | VAF 16/462 reads (3%) | catalogued as COSV53697663; called by muse, mutect2
- KMT2B | c.5047C>T p.Q1683* | Nonsense Mutation (SNP) | VAF 34/98 reads (35%) | catalogued as COSV55858068; called by muse, mutect2, varscan2
- KPNA6 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs201663407; called by muse, mutect2, varscan2
- KRT31 | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.587); catalogued as COSV52435392; called by muse, mutect2, varscan2
- KRT84 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.443); catalogued as COSV57771881; called by muse, mutect2
- KTN1 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1207357368, COSV101255462; called by muse, mutect2, varscan2
- KTN1 | c.3094C>T p.L1032F | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV58540413; called by muse, mutect2, varscan2
- LDB3 | c.1874T>C p.L625S | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53942093; called by muse, mutect2
- LDLR | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs750126678, CM003153, COSV52941979; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LELP1 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV64202472; called by muse, mutect2, varscan2
- LEPR | c.3102G>T p.Q1034H | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV62748506; called by muse, mutect2, varscan2
- LGR4 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.735); catalogued as rs376236224; called by muse, mutect2, varscan2
- LHX5 | c.557C>A p.T186N | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55662932; called by muse, mutect2, varscan2
- LINGO1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs763246298, COSV62437111; called by muse, mutect2, varscan2
- LIPG | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54296477; called by muse, mutect2, varscan2
- LIPJ | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 162/492 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV64245579; called by muse, mutect2, varscan2
- LMBR1L | c.694C>G p.R232G | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV99918614, COSV99919029; called by muse, mutect2, varscan2
- LMO7 | c.584A>T p.D195V (on ENST00000357063; = p.D210V on NM_005358.5) | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58537519; called by muse, mutect2, varscan2
- LRP1B | c.7978G>A p.D2660N | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1227215052, COSV67224033; called by muse, mutect2, varscan2
- LRP1B | c.3869C>T p.T1290I | Missense Mutation (SNP) | VAF 136/489 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV67224037, COSV67256616; called by muse, mutect2, varscan2
- LRRC43 | c.1680del p.I561Sfs*10 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs748039371; called by mutect2, pindel, varscan2
- LRRC4B | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65350128; called by muse, varscan2
- LRRC66 | c.1575G>T p.Q525H | Missense Mutation (SNP) | VAF 72/271 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.737); catalogued as rs1398150584, COSV58634093; called by muse, mutect2, varscan2
- LRRC66 | c.1104dup p.E369Rfs*34 | Frame Shift Ins (INS) | VAF 22/148 reads (15%) | catalogued as rs763806659; called by mutect2, pindel, varscan2
- LRRIQ4 | c.1482A>G p.I494M | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV61619293; called by muse, mutect2, varscan2
- LTBP1 | c.3274G>A p.G1092R (on ENST00000404816 / NM_206943.4; = p.G766R on NM_000627.4) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs774524181, COSV55379641; called by muse, mutect2, varscan2
- LTBP2 | c.3164G>A p.C1055Y | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56208619; called by muse, mutect2, varscan2
- LYST | c.10390A>G p.I3464V | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as COSV67707280; called by muse, mutect2, varscan2
- MAF | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58154289; called by muse, varscan2
- MAF | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58154296; called by muse, varscan2
- MAFF | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1433992382, COSV100633175; called by muse, varscan2
- MAGEC3 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV53580779; called by muse, mutect2, varscan2
- MANEAL | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV61116083; called by muse, mutect2, varscan2
- MAP1S | c.2345C>T p.T782M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1380945130, COSV100141265; called by muse, mutect2, varscan2
- MAP2K1 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1473690179, COSV61070930; called by muse, mutect2, varscan2
- MAP3K1 | c.2250T>A p.N750K | Missense Mutation (SNP) | VAF 98/336 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV68123975; called by muse, mutect2, varscan2
- MAP3K14 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.185); catalogued as COSV100766572; called by muse, mutect2, varscan2
- MAP3K8 | c.751C>A p.H251N | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53919865; called by muse, mutect2, varscan2
- MAP4K3 | c.80A>G p.Y27C | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55713437; called by muse, mutect2, varscan2
- MAP4K4 | c.2101G>A p.G701R (on ENST00000347699 / NM_001242559.2; = p.G616R on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (1); catalogued as rs776570846, COSV56331834; called by muse, mutect2, varscan2
- MAP4K4 | c.3150G>T p.W1050C (on ENST00000347699 / NM_001242559.2; = p.W968C on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56331852; called by muse, mutect2, varscan2
- MAPK10 | c.566G>A p.R189H (on ENST00000359221 / NM_001351625.2; = p.R227H on NM_002753.5) | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as rs752620406, COSV60382973; called by muse, mutect2, varscan2
- MAPK6 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 78/333 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55930064; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3373G>A p.V1125M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99169803; called by muse, mutect2
- MARCHF4 | c.1139C>A p.T380N | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as COSV56105185; called by muse, mutect2, varscan2
- MBOAT7 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as COSV99825092; called by muse, mutect2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 56/90 reads (62%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCTP2 | c.2295G>T p.Q765H | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63293816; called by muse, mutect2, varscan2
- MED19 | c.474G>A p.P158= | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as rs778299132, COSV54706827; called by muse, mutect2, varscan2
- MEGF6 | c.4610G>A p.G1537E | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.041); catalogued as COSV53890306; called by muse, mutect2, varscan2
- MEGF8 | c.3912G>T p.W1304C (on ENST00000251268 / NM_001271938.2; = p.W1237C on NM_001410.3) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52086112; called by muse, mutect2, varscan2
- MEI1 | c.3769C>T p.Q1257* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as rs1168113108, COSV99740851; called by muse, mutect2, varscan2
- MGA | c.4682C>T p.T1561I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.143); catalogued as rs769653790, COSV54954682; called by mutect2, varscan2
- MGA | c.7303C>T p.R2435W (on ENST00000219905 / NM_001164273.1; = p.R2226W on NM_001080541.2) | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779811318, COSV54947919; called by muse, mutect2, varscan2
- MICALL2 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV99876298; called by muse, mutect2, varscan2
- MIS18A | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs764293569, COSV51589328; called by muse, mutect2, varscan2
- MLF1 | c.804del p.K268Nfs*3 | Frame Shift Del (DEL) | VAF 55/217 reads (25%) | catalogued as rs1289728341; called by mutect2, pindel, varscan2
- MLIP | c.459del p.I154Lfs*11 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs767692253; called by mutect2, pindel, varscan2
- MLLT1 | c.1381del p.Q461Rfs*46 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs772076449; called by mutect2, varscan2
- MMUT | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 113/317 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.977); catalogued as rs141829043, COSV99222332; called by muse, mutect2, varscan2
- MN1 | c.3457del p.L1153Wfs*25 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs1359870052; called by mutect2, pindel
- MN1 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.09); catalogued as COSV56563454; called by muse, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 40/136 reads (29%) | catalogued as rs757379917; called by mutect2, varscan2
- MORC3 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs780018142, COSV68203608; called by muse, mutect2, varscan2
- MOV10L1 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV53172183; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3139dup p.T1047Nfs*4 | Frame Shift Ins (INS) | VAF 62/236 reads (26%) | catalogued as rs756998270; called by mutect2, pindel, varscan2
- MRGPRX1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs1244425426, COSV57107509, COSV57110283; called by muse, mutect2, varscan2
- MROH1 | c.2588G>A p.R863Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs1477143754; called by muse, mutect2, varscan2
- MRPL18 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100365083; called by muse, mutect2, varscan2
- MRPS22 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV60350179; called by muse, mutect2, varscan2
- MRPS25 | c.329+2T>C p.X110_splice | Splice Site (SNP) | VAF 91/415 reads (22%) | catalogued as COSV53741475; called by muse, mutect2, varscan2
- MSGN1 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55262980; called by muse, mutect2, varscan2
- MTARC2 | c.554A>T p.N185I | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as COSV63765627; called by muse, mutect2, varscan2
- MTMR4 | c.3121C>T p.R1041* | Nonsense Mutation (SNP) | VAF 65/189 reads (34%) | catalogued as COSV60200790; called by muse, mutect2, varscan2
- MTSS1 | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61497246; called by muse, mutect2, varscan2
- MTTP | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55506022; called by muse, mutect2
- MUC16 | c.14939C>A p.P4980H | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.028); catalogued as COSV67468789; called by muse, mutect2, varscan2
- MUC17 | c.11701G>A p.D3901N | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.709); catalogued as COSV60289709; called by muse, mutect2, varscan2
- MUC5B | c.7720G>A p.V2574I | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV71592156; called by muse, mutect2, varscan2
- MUC5B | c.12350C>T p.S4117L | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs558005823, COSV101500835; called by mutect2, varscan2
- MUC5B | c.15415C>T p.H5139Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV101500836; called by muse, mutect2, varscan2
- MXD1 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs767887648, COSV52479858; called by muse, mutect2, varscan2
- MXRA8 | c.982A>G p.N328D | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV100492121; called by muse, mutect2
- MYBBP1A | c.2945T>C p.L982P | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54598014; called by muse, mutect2
- MYC | c.425C>T p.A142V (on ENST00000377970; = p.A157V on NM_002467.6) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV52373227; called by muse, mutect2, varscan2
- MYCBP2 | c.12104G>A p.R4035H (on ENST00000357337; = p.R4073H on NM_015057.5) | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.976); catalogued as rs1209939503, COSV62020764; called by muse, mutect2, varscan2
- MYCBP2 | c.11839C>T p.R3947C (on ENST00000357337; = p.R3985C on NM_015057.5) | Missense Mutation (SNP) | VAF 67/428 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1331100566, COSV62020785; called by muse, mutect2, varscan2
- MYO3A | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 51/147 reads (35%) | catalogued as rs749269594, COSV56332145; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9A | c.6379A>G p.I2127V | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV100614384; called by muse, mutect2, varscan2
- MYO9A | c.5807C>T p.T1936M | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs779857942, COSV100614385; called by muse, mutect2, varscan2
- MYOF | c.6124G>A p.A2042T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV63704709; called by muse, mutect2, varscan2
- NAV3 | c.6578G>A p.R2193Q (on ENST00000397909 / NM_001024383.2; = p.R2171Q on NM_014903.6) | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs772821927, COSV57081994; called by muse, mutect2, varscan2
- NCCRP1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs759181864, COSV59212284; called by muse, mutect2, varscan2
- NCKIPSD | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53661130; called by muse, varscan2
- NCKIPSD | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.52); catalogued as rs748852507, COSV99584299; called by muse, varscan2
- NCOA2 | c.3956C>T p.T1319M | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as rs774257324, COSV51219736; called by muse, mutect2, varscan2
- NDST2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752636610, COSV55214661; called by muse, mutect2, varscan2
- NEB | c.6389C>T p.A2130V | Missense Mutation (SNP) | VAF 195/576 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV51420054; called by muse, mutect2, varscan2
- NEB | c.2598G>T p.K866N | Missense Mutation (SNP) | VAF 152/539 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51420084, COSV51449487; called by muse, mutect2, varscan2
- NEK10 | c.922C>A p.L308I | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58281464, COSV58282913; called by muse, mutect2, varscan2
- NEURL4 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as COSV59749961; called by muse, mutect2, varscan2
- NEUROD1 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV54549001; called by muse, mutect2, varscan2
- NF1 | c.4560G>C p.Q1520H (on ENST00000358273 / NM_001042492.3; = p.Q1499H on NM_000267.3) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as COSV62204908, COSV62205331, COSV62211971; called by muse, mutect2, varscan2
- NF2 | c.514del p.R172Gfs*2 | Frame Shift Del (DEL) | VAF 56/198 reads (28%) | catalogued as COSV58525355; called by mutect2, pindel, varscan2
- NHLH1 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1303382399, COSV57484449; called by muse, mutect2, varscan2
- NKX6-1 | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 128/402 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55684792; called by muse, mutect2, varscan2
- NLK | c.986G>A p.C329Y | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63490610; called by muse, mutect2, varscan2
- NLRP12 | c.2188del p.V730* | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | catalogued as rs771632319; called by mutect2, varscan2
- NLRP4 | c.1578G>C p.E526D | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV56711128, COSV56714631, COSV56721582; called by muse, mutect2, varscan2
- NLRP5 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs367708838; called by muse, varscan2
- NLRP5 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs780213439, COSV66764769; called by muse, varscan2
- NLRX1 | c.2309T>C p.L770P | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV52705098; called by muse, mutect2, varscan2
- NOL6 | c.354G>T p.R118S | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV53042076; called by muse, mutect2, varscan2
- NOS1 | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 94/350 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1470536078, COSV57613018; called by muse, mutect2, varscan2
- NPAS3 | c.350G>A p.R117Q (on ENST00000356141 / NM_001164749.2; = p.R87Q on NM_022123.3) | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs777443078, COSV58087112; called by muse, mutect2, varscan2
- NPEPL1 | c.1314C>G p.N438K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV61939165; called by muse, mutect2, varscan2
- NPNT | c.763+2T>A p.X255_splice | Splice Site (SNP) | VAF 18/274 reads (7%) | catalogued as COSV59755844; called by muse, mutect2
- NR5A2 | c.626T>C p.I209T (on ENST00000367362 / NM_205860.3; = p.I163T on NM_003822.5) | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as COSV52650731; called by muse, mutect2, varscan2
- NRDC | c.3340C>T p.Q1114* | Nonsense Mutation (SNP) | VAF 34/120 reads (28%) | catalogued as COSV61404620; called by muse, mutect2, varscan2
- NRDE2 | c.3034C>T p.H1012Y | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100583665; called by muse, mutect2, varscan2
- NRG1 | c.848G>A p.R283Q (on ENST00000405005 / NM_013964.5; = p.R288Q on NM_013956.5) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as rs145033301, COSV99829962; called by muse, mutect2, varscan2
- NRN1 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV55205957; called by muse, mutect2, varscan2
- NRROS | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1218325787, COSV60744988; called by muse, mutect2, varscan2
- NRXN2 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.436); catalogued as COSV99635930; called by muse, mutect2, varscan2
- NRXN3 | c.2223del p.R742Vfs*8 (on ENST00000335750 / NM_001330195.2; = p.R369Vfs*8 on NM_004796.6) | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | catalogued as COSV59808471; called by mutect2, pindel, varscan2
- NSD2 | c.1410G>T p.E470D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as COSV100372955, COSV56396364; called by muse, mutect2, varscan2
- NTNG1 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 51/322 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV64271968; called by muse, mutect2, varscan2
- NTNG2 | c.523T>C p.F175L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100647772; called by muse, mutect2, varscan2
- NUAK1 | c.1822C>A p.L608I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.243); catalogued as COSV99777352; called by muse, mutect2, varscan2
- NUF2 | c.1201dup p.I401Nfs*2 | Frame Shift Ins (INS) | VAF 123/463 reads (27%) | catalogued as rs1557956181; called by mutect2, pindel, varscan2
- NUMA1 | c.5899C>T p.R1967* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | catalogued as rs987854742, COSV52621136, COSV99474828; called by muse, mutect2, varscan2
- NUMA1 | c.2960C>T p.A987V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1223031309, COSV61185933; called by muse, mutect2, varscan2
- NUMA1 | c.1024A>G p.N342D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV100706661; called by muse, mutect2, varscan2
- NUP210 | c.403del p.L135Wfs*3 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as rs762804106; called by mutect2, pindel, varscan2
- NWD1 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs759220842, COSV60343108; called by mutect2, varscan2
- NXPE1 | c.1316G>A p.G439D (on ENST00000424269; = p.G297D on NM_152315.5) | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52629609; called by muse, mutect2, varscan2
- NXPE3 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs147008534, COSV56290723; called by muse, mutect2, varscan2
- OCRL | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 103/279 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV63980962; called by muse, mutect2, varscan2
- OGA | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63381804; called by muse, mutect2, varscan2
- OMD | c.149A>C p.D50A | Missense Mutation (SNP) | VAF 108/352 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV100979093; called by muse, mutect2, varscan2
- OOEP | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs1054721483, COSV64859273; called by muse, mutect2, varscan2
- OPRD1 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs1205082434, COSV52382023; called by muse, varscan2
- OPRK1 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99654418; called by muse, varscan2
- OPRPN | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 43/244 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV68192963; called by muse, mutect2, varscan2
- OR2A25 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs756605755, COSV68716912; called by muse, mutect2, varscan2
- OR2D3 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 156/614 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs138058537; called by muse, mutect2, varscan2
- OR4D5 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 56/446 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58306366, COSV58307167; called by muse, mutect2, varscan2
- OR4D9 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV61434775; called by muse, mutect2, varscan2
- OR4K17 | c.900del p.K300Nfs*7 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | catalogued as rs1202978308; called by mutect2, pindel, varscan2
- OR4L1 | c.772T>A p.Y258N | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59849870; called by muse, mutect2, varscan2
- OR5M3 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV56566955; called by muse, mutect2, varscan2
- ORAI2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs372227034; called by muse, mutect2, varscan2
- OXT | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.335); catalogued as COSV99459216; called by muse, mutect2, varscan2
- P3H2 | c.1925T>C p.I642T | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs757821033, COSV60022073; called by muse, mutect2, varscan2
- PABPC1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 195/590 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as COSV59398489; called by muse, mutect2, varscan2
- PADI1 | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as rs1265905752, COSV100969291; called by muse, mutect2, varscan2
- PAN3 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 103/473 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV56703631; called by muse, mutect2, varscan2
- PAPPA | c.4568G>A p.R1523H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs769001950, COSV60277901; called by muse, mutect2, varscan2
- PAQR8 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV62442679; called by muse, mutect2
- PARP10 | c.2805dup p.N936Qfs*6 | Frame Shift Ins (INS) | VAF 8/23 reads (35%) | catalogued as rs1375069936; called by mutect2, pindel, varscan2
- PARP8 | c.1247G>T p.R416I | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.991); catalogued as rs1168152687, COSV55860470, COSV99892916; called by muse, mutect2, varscan2
- PAX7 | c.34A>G p.M12V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100946985; called by muse, mutect2, varscan2
- PCDH11X | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 168/569 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs760129843, COSV53441719, COSV53494306; called by muse, mutect2, varscan2
- PCDH12 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as rs781200540, COSV51519233; called by muse, mutect2, varscan2
- PCDH17 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1375857261, COSV64972185, COSV64973052, COSV64974497; called by muse, varscan2
- PCDH7 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62343246; called by muse, mutect2, varscan2
- PCDHA13 | c.1985C>T p.T662M | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as rs1356283866, COSV56477666, COSV99170418; called by muse, mutect2, varscan2
- PCDHGA8 | c.1711G>T p.G571C | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53919151, COSV53939222, COSV53955417; called by muse, mutect2, varscan2
- PCDHGB1 | c.1741G>A p.G581S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1036324795, COSV53927679, COSV53955402; called by muse, mutect2, varscan2
- PCGF5 | c.326-2A>G p.X109_splice | Splice Site (SNP) | VAF 21/74 reads (28%) | catalogued as COSV60238053; called by muse, mutect2
- PCIF1 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs145800939; called by muse, mutect2, varscan2
- PDE6C | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs542292048, COSV65115987; called by muse, mutect2, varscan2
- PDK4 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 42/162 reads (26%) | catalogued as rs139435831, COSV50011390; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PEAK1 | c.3778C>T p.P1260S | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV56936361; called by muse, mutect2, varscan2
- PEAR1 | c.3012del p.G1005Afs*57 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs750264783; called by mutect2, pindel, varscan2
- PFKP | c.1155-1G>A p.X385_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as COSV66898040; called by muse, mutect2, varscan2
- PHKA1 | c.2995C>T p.R999* | Nonsense Mutation (SNP) | VAF 145/431 reads (34%) | catalogued as rs1556244092, COSV59806111; called by muse, mutect2, varscan2
- PHLDA1 | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 62/568 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV56998077; called by muse, mutect2, varscan2
- PHLPP1 | c.4714A>C p.S1572R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.184); catalogued as COSV53029387; called by muse, mutect2
- PHYH | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752028596, COSV53815952; called by muse, mutect2, varscan2
- PIEZO2 | c.7473del p.E2492Kfs*3 | Frame Shift Del (DEL) | VAF 118/454 reads (26%) | catalogued as COSV99554450; called by mutect2, pindel, varscan2
- PIGQ | c.1888G>A p.A630T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs146507621; called by muse, mutect2, varscan2
- PIK3CD | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs1557659540, COSV63127006; called by muse, mutect2, varscan2
- PITPNM1 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs766305895, COSV54160800; called by muse, mutect2, varscan2
- PIWIL1 | c.2503G>A p.A835T | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745487305, COSV55347041, COSV55349697; called by muse, mutect2, varscan2
- PKIG | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); catalogued as COSV63068947; called by muse, mutect2, varscan2
- PLA2G4F | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as rs773748065, COSV101215407; called by muse, mutect2, varscan2
- PLA2R1 | c.4025G>A p.R1342Q | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as rs766943394, COSV51774768; called by muse, mutect2, varscan2
- PLA2R1 | c.3605A>G p.E1202G | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as COSV51779190; called by muse, mutect2, varscan2
- PLB1 | c.2335G>A p.G779S | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as rs745846549, COSV59826264; called by muse, mutect2, varscan2
- PLCB3 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54188794; called by muse, mutect2, varscan2
- PLEKHH3 | c.1947C>G p.Y649* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV52217794; called by muse, mutect2, varscan2
- PLEKHH3 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52217799; called by muse, mutect2, varscan2
- PLEKHM2 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); catalogued as COSV65396348; called by muse, mutect2, varscan2
- PLEKHN1 | c.988_990del p.K330del (on ENST00000379409; = p.K278del on NM_032129.3 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 33/113 reads (29%) | catalogued as rs768926690; called by mutect2, pindel, varscan2
- PLG | c.761G>T p.W254L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99805154; called by muse, mutect2
- PLG | c.2314T>C p.Y772H | Missense Mutation (SNP) | VAF 46/898 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100369603; called by muse, mutect2
- PLS3 | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 26/408 reads (6%) | catalogued as COSV99172464; called by muse, mutect2
- PLXNA2 | c.5513G>A p.R1838H | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs563402733, COSV65441054; called by muse, mutect2, varscan2
- PLXNA3 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 57/146 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.065); catalogued as COSV63754173; called by muse, mutect2, varscan2
- PLXNA4 | c.3967C>T p.R1323W | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747801776, COSV58104969; called by muse, mutect2, varscan2
- POFUT2 | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV57959131; called by muse, mutect2, varscan2
- POGZ | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1233807937, COSV55036107; called by muse, mutect2
- POLD1 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101486932; called by muse, mutect2
- POLR2F | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as rs778818192, COSV68411757; called by muse, mutect2, varscan2
- POM121C | c.3599C>T p.A1200V (on ENST00000607367; = p.A958V on NM_001099415.3) | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs370125686; called by muse, mutect2
- POU3F3 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV63721485; called by muse, mutect2, varscan2
- PPP1R12C | c.1110del p.I373Sfs*51 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as COSV54738562; called by mutect2, varscan2
- PPP1R18 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV51296312; called by muse, varscan2
- PPP2R2C | c.1139A>G p.E380G | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); catalogued as rs754747800, COSV59444489; called by muse, mutect2, varscan2
- PPP2R5D | c.1619C>T p.T540I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.065); catalogued as rs769459377, COSV55145100, COSV55146861; called by muse, mutect2, varscan2
- PPP2R5E | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV61742054; called by muse, varscan2
- PPT2 | c.814del p.A272Pfs*2 | Frame Shift Del (DEL) | VAF 50/159 reads (31%) | catalogued as COSV61353901, COSV61353944; called by mutect2, pindel, varscan2
- PRADC1 | c.489G>T p.W163C | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.839); catalogued as COSV57820330; called by muse, mutect2, varscan2
- PRCC | c.961del p.E322Nfs*105 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | catalogued as COSV54855007; called by mutect2, pindel
- PRDM14 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52572626; called by muse, mutect2, varscan2
- PRDM5 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV53361078; called by muse, mutect2, varscan2
- PRDX1 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as rs1189724499, COSV53113829; called by muse, varscan2
- PRKD3 | c.1374G>T p.K458N | Missense Mutation (SNP) | VAF 125/377 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52213757; called by muse, mutect2, varscan2
- PROSER2 | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53205878; called by muse, mutect2, varscan2
- PRPF3 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs1553866840, COSV61394377; called by muse, mutect2, varscan2
- PRPF31 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320135; called by muse, mutect2, varscan2
- PRPF38A | c.839A>G p.K280R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as COSV57122484; called by muse, mutect2, varscan2
- PRRC2C | c.1204C>T p.R402C (on ENST00000367742; = p.R400C on NM_015172.4) | Missense Mutation (SNP) | VAF 152/483 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs1379965356, COSV58905969; called by muse, mutect2, varscan2
- PRSS21 | c.731G>A p.C244Y | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771479192, COSV50051505; called by muse, mutect2, varscan2
- PRSS36 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | catalogued as COSV51637525; called by muse, mutect2, varscan2
- PSD | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV50048566, COSV99194055; called by muse, varscan2
- PSMB8 | c.421C>T p.R141* (on ENST00000374882 / NM_148919.4; = p.R137* on NM_004159.5) | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as rs374929612; called by muse, mutect2, varscan2
- PTBP2 | c.691C>G p.L231V (on ENST00000426398 / NM_001300986.2; = p.L223V on NM_021190.4) | Missense Mutation (SNP) | VAF 289/861 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV64624614; called by muse, mutect2, varscan2
- PTPN13 | c.6493G>A p.D2165N (on ENST00000411767 / NM_080683.3; = p.D2146N on NM_006264.3) | Missense Mutation (SNP) | VAF 185/558 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV57408293; called by muse, mutect2, varscan2
- PTPN6 | c.1584G>A p.S528= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as rs782111333, COSV59684663; called by muse, varscan2
- PTPRC | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs138554556, COSV61414421; called by muse, mutect2, varscan2
- PTPRT | c.3491G>A p.S1164N | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1379394015, COSV61983531; called by muse, mutect2, varscan2
- PTPRU | c.3717C>T p.D1239= | Splice Region (SNP) | VAF 8/23 reads (35%) | catalogued as rs367662634; called by muse, mutect2, varscan2
- PUS7L | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100786516; called by muse, mutect2, varscan2
- PYGB | c.1620G>T p.Q540H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as COSV53818828; called by muse, mutect2, varscan2
- QPRT | c.779G>A p.C260Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV54879239; called by muse, varscan2
- QRFPR | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100543808, COSV57677366; called by muse, mutect2, varscan2
- QRSL1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 156/427 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1037765160, COSV64687536; called by muse, mutect2, varscan2
- RAB11A | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV56041945; called by muse, mutect2, varscan2
- RAB11B | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs1250398546, COSV60085657; called by muse, mutect2, varscan2
- RAB33B | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59777422; called by muse, mutect2, varscan2
- RAD17 | c.1555T>A p.S519T (on ENST00000380774 / NM_133339.2; = p.S508T on NM_002873.1) | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.324); catalogued as COSV99281792; called by muse, mutect2, varscan2
- RAG1 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as rs778391388, COSV55024800; called by muse, mutect2, varscan2
- RAI2 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.41); catalogued as COSV58964478; called by muse, mutect2, varscan2
- RALGAPB | c.2699A>G p.E900G | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV53438070; called by muse, mutect2, varscan2
- RARS1 | c.1880T>C p.I627T | Missense Mutation (SNP) | VAF 29/393 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as rs1313652711, COSV99199236; called by muse, mutect2
- RASGRP3 | c.1634G>T p.R545M (on ENST00000402538 / NM_001349975.2; = p.R544M on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67822223; called by mutect2, varscan2
- RBM15B | c.2529del p.S844Pfs*27 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs781825075; called by mutect2, varscan2
- RBM25 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.953); catalogued as rs917419694, COSV56201768; called by muse, mutect2, varscan2
- RBM33 | c.3089dup p.L1031Pfs*109 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs766836538; called by mutect2, varscan2
- RBM39 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.885); catalogued as rs1215706067, COSV53615480; called by muse, mutect2
- RBM43 | c.213dup p.V72Sfs*18 | Frame Shift Ins (INS) | VAF 59/199 reads (30%) | catalogued as rs746242773; called by mutect2, varscan2
- REEP2 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs756864410, COSV99649780; called by muse, mutect2, varscan2
- REEP4 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs138280096, COSV100098286; called by muse, varscan2
- REPIN1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs376711625; called by muse, mutect2, varscan2
- RETREG3 | c.1013T>C p.M338T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99519111; called by muse, mutect2, varscan2
- RGMA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs763987490, COSV61233202; called by muse, mutect2, varscan2
- RGS9 | c.1729C>T p.R577C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs756410417, COSV99288104; called by muse, mutect2, varscan2
- RHBDD2 | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as COSV50087070; called by muse, mutect2, varscan2
- RHBDD3 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs751207459, COSV53323534; called by muse, mutect2, varscan2
- RHBDD3 | c.701C>A p.P234H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as COSV99328594, COSV99328635; called by muse, varscan2
- RIF1 | c.6469T>C p.S2157P | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as rs1300343175, COSV99691303; called by muse, mutect2
- RITA1 | c.291_293del p.K97del | In Frame Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs769176263; called by pindel, varscan2
- RND2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV56816452; called by muse, mutect2, varscan2
- RNF213 | c.7276A>G p.K2426E | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60398381; called by muse, mutect2, varscan2
- RNF43 | c.599G>A p.W200* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV68459246; called by muse, mutect2, varscan2
- ROBO1 | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71394645; called by muse, mutect2, varscan2
- ROPN1B | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99305702; called by muse, mutect2, varscan2
- RPAP1 | c.2977G>T p.G993* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | catalogued as COSV58539268; called by muse, mutect2, varscan2
- RPGRIP1L | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 72/267 reads (27%) | catalogued as rs745413543, COSV100046009, COSV50903640; called by muse, mutect2, varscan2
- RPL27 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.215); catalogued as rs760389648, COSV53814591; called by muse, mutect2, varscan2
- RRP1B | c.1489A>G p.M497V | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100513264; called by muse, mutect2
- RSAD2 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs779529246, COSV65908369; called by muse, mutect2, varscan2
- RTP5 | c.674dup p.A226Cfs*12 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs35989328; called by mutect2, varscan2
- RUBCN | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs546982384, COSV56366773; called by muse, mutect2, varscan2
- RYR2 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 136/446 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as rs1306256963, COSV100773105; called by muse, varscan2
- RYR2 | c.2845C>T p.H949Y | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV63687381; called by muse, mutect2, varscan2
- RYR2 | c.6430C>T p.R2144C | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs770847446, COSV63685337, COSV63687390; called by muse, mutect2, varscan2
- SAC3D1 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs775031585, COSV57248406; called by mutect2, varscan2
- SAE1 | c.689A>T p.K230M | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV54295613; called by muse, mutect2, varscan2
- SAFB | c.1213_1215del p.G405del | In Frame Del (DEL) | VAF 88/335 reads (26%) | catalogued as rs762859329; called by mutect2, pindel, varscan2
- SALL2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781310209, COSV58103473; called by muse, mutect2, varscan2
- SARDH | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1366811300, COSV53832611, COSV53833571; called by muse, mutect2
- SASH3 | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63556005; called by muse, mutect2, varscan2
- SASS6 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.067); catalogued as rs749784408, COSV54928102; called by muse, mutect2, varscan2
- SAXO1 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1216220361, COSV65870287; called by muse, mutect2, varscan2
- SBF2 | c.1997A>G p.Q666R | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.491); catalogued as COSV56299725; called by muse, mutect2
- SCAP | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99653267; called by muse, mutect2, varscan2
- SCN8A | c.5560C>T p.R1854W | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61982276; called by muse, mutect2, varscan2
- SCN9A | c.5836dup p.T1946Nfs*14 (on ENST00000303354; = p.T1935Nfs*14 on NM_002977.3) | Frame Shift Ins (INS) | VAF 221/845 reads (26%) | catalogued as rs1558938569; called by mutect2, pindel, varscan2
- SCRT2 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99857281; called by muse, varscan2
- SCYL1 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs981212419, COSV54212826; called by muse, mutect2, varscan2
- SDK1 | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as rs1443429729, COSV101269895; called by muse, mutect2, varscan2
- SEC14L1 | c.1098C>T p.Y366= | Splice Region (SNP) | VAF 8/32 reads (25%) | catalogued as rs1471594951, COSV66722475; called by muse, varscan2
- SEC16A | c.2176_2177del p.W726Gfs*4 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs1485129630; called by pindel, varscan2
- SEMA5B | c.2246G>T p.C749F | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1307328940, COSV52098785; called by muse, mutect2, varscan2
- SEMA6A | c.2281A>G p.T761A | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99145988; called by muse, mutect2, varscan2
- SEMA6B | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100015160; called by muse, mutect2, varscan2
- SERPINB13 | c.478dup p.I160Nfs*11 | Frame Shift Ins (INS) | VAF 62/179 reads (35%) | catalogued as rs750002811; called by mutect2, pindel, varscan2
- SERPINE1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV56169760, COSV56169835; called by muse, mutect2, varscan2
- SERPINE3 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV68545338; called by muse, mutect2, varscan2
- SETBP1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs140717709; called by muse, varscan2
- SF3A2 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99678105; called by muse, mutect2, varscan2
- SFI1 | c.1920G>A p.M640I (on ENST00000400288 / NM_001007467.3; = p.M609I on NM_014775.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.213); catalogued as COSV101192317; called by muse, mutect2
- SFTPB | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.157); catalogued as COSV60893366; called by muse, mutect2, varscan2
- SGK2 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs147953497; called by muse, mutect2, varscan2
- SGPP1 | c.821T>C p.F274S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55975504; called by muse, mutect2, varscan2
- SH3BP1 | c.1735del p.Q579Rfs*79 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | catalogued as rs70950549; called by mutect2, pindel
- SH3BP4 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); catalogued as COSV60644054; called by muse, mutect2, varscan2
- SH3GLB2 | c.165G>T p.K55N | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV65330982; called by muse, mutect2, varscan2
- SH3RF1 | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV52920968; called by muse, mutect2, varscan2
- SHC2 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs746427249, COSV52744611; called by muse, mutect2, varscan2
- SHLD2 | c.1542G>T p.E514D | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV53955374; called by muse, mutect2, varscan2
- SHROOM3 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as rs746996342, COSV56029866; called by muse, mutect2, varscan2
- SIGLEC1 | c.1952del p.G651Vfs*13 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs777478941; called by mutect2, pindel, varscan2
- SIGLEC8 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV58473994; called by muse, mutect2, varscan2
- SKIV2L | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 49/176 reads (28%) | catalogued as COSV64811853; called by muse, mutect2, varscan2
- SLC18A3 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1417056757, COSV60325575; called by muse, mutect2, varscan2
- SLC1A6 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs1023555551, COSV55670689; called by muse, mutect2, varscan2
- SLC22A2 | c.864G>T p.R288S | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65266610; called by muse, mutect2
- SLC25A29 | c.805G>A p.V269I (on ENST00000359232 / NM_001039355.3; = p.V203I on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1342439298, COSV100821199; called by muse, mutect2, varscan2
- SLC25A51 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 95/294 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs373004614; called by muse, mutect2, varscan2
- SLC27A3 | c.1902G>T p.E634D (on ENST00000271857; = p.E506D on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); catalogued as COSV99670197; called by muse, mutect2, varscan2
- SLC2A13 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55118162; called by muse, mutect2, varscan2
- SLC34A3 | c.1733del p.P578Rfs*63 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs1353078679; called by mutect2, pindel, varscan2
- SLC45A2 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs150033963, COSV56875351; called by muse, mutect2, varscan2
- SLC4A1AP | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.236); catalogued as COSV58135041; called by muse, mutect2, varscan2
- SLC4A1AP | c.1364C>A p.A455D | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV58135054; called by muse, mutect2, varscan2
- SLC5A1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 134/451 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as CM961338, COSV56688022, COSV99833763; called by muse, mutect2, varscan2
- SLC66A1 | c.59A>G p.Q20R | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100913340; called by muse, mutect2, varscan2
- SLC6A2 | c.1690T>C p.S564P | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99574668; called by muse, mutect2, varscan2
- SLIT1 | c.1676G>A p.G559E | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56588562, COSV99822607; called by muse, mutect2
711 further variants in this file (350 protein-altering or splice-affecting, 331 silent, 30 other) are not listed here.
